Somatic mutation profile of tumor specimen ALCH-ADI6-TTP1-A (aliquot ALCH-ADI6-TTP1-A-1-0-D-A565-36) from ALCHEMIST case ALCH-ADI6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.5 years (22,842 days).
Specimen ALCH-ADI6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b81ceef0-9574-4fd0-98ea-748716cd7a04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADI6-NB1-A (Blood Derived Normal), aliquot ALCH-ADI6-NB1-A-1-0-D-A565-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e9ba69e-76bd-44bb-bb50-530acdd11086

The open-access MAF lists 935 somatic variants for this specimen: 652 protein-altering or splice-affecting, 166 silent, 117 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 575, Silent 166, Intron 53, Nonsense Mutation 49, RNA 22, 3'UTR 21, Splice Site 16, 5'Flank 10, 5'UTR 8, Frame Shift Del 6, Splice Region 3, 3'Flank 3.

Variants (750 of 935; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 48/597 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCA10 | c.3313G>T p.D1105Y | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV52228026; called by muse, mutect2
- ABCB1 | c.1984C>A p.L662I | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99712017; called by muse, mutect2
- ACSBG1 | c.1341G>C p.K447N | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.727); catalogued as COSV51908556; called by muse, mutect2
- ACSM4 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV68067011; called by muse, mutect2
- ADAMTS12 | c.281G>T p.R94I | Missense Mutation (SNP) | VAF 38/796 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV100710941; called by muse, mutect2
- ADAMTS19 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 16/172 reads (9%) | catalogued as COSV50741469; called by muse, mutect2
- ADAMTS2 | c.2033C>A p.T678K | Missense Mutation (SNP) | VAF 40/617 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99281346; called by muse, mutect2
- ADCY2 | c.1861G>A p.V621M | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs149172094; called by muse, mutect2, varscan2
- ADGRL3 | c.4538C>G p.P1513R (on ENST00000506720 / NM_001322402.2; = p.P1402R on NM_015236.6) | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.167); catalogued as COSV72229667, COSV72230592; called by muse, mutect2
- AGL | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.288); catalogued as rs746265668, COSV54052510; called by muse, mutect2
- AHNAK2 | c.6328C>A p.P2110T | Missense Mutation (SNP) | VAF 50/418 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1333283348; called by muse, mutect2, varscan2
- ANKRD33B | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 40/502 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.743); catalogued as COSV56977155; called by muse, mutect2
- APOB | c.7013G>A p.R2338K | Missense Mutation (SNP) | VAF 41/398 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.36); catalogued as rs899191101; called by muse, mutect2, varscan2
- AQP2 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 54/544 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as rs143886391; called by muse, mutect2
- ARHGAP22 | c.378G>T p.M126I | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV50986811; called by muse, mutect2, varscan2
- ARHGAP40 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 55/523 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs750789487; called by muse, mutect2, varscan2
- ARX | c.166A>G p.S56G | Missense Mutation (SNP) | VAF 68/902 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs144098296; ClinVar: likely benign; called by muse, mutect2
- ASCC3 | c.6453A>G p.I2151M | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs576990608, COSV100976401; called by muse, mutect2
- ASTN2 | c.1711G>T p.D571Y (on ENST00000313400 / NM_001365069.1; = p.D520Y on NM_014010.5) | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV57796774; called by muse, mutect2
- ATP13A1 | c.3451G>A p.G1151S | Missense Mutation (SNP) | VAF 57/500 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.838); catalogued as rs1239647244, COSV99179374; called by muse, mutect2, varscan2
- BRICD5 | c.755C>A p.S252* (on ENST00000562360; = p.S220* on NM_182563.3) | Nonsense Mutation (SNP) | VAF 16/136 reads (12%) | catalogued as COSV57026417, COSV57030922; called by muse, mutect2, varscan2
- BRINP3 | c.53G>T p.W18L | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV66514424; called by muse, mutect2
- BTBD8 | c.3346G>A p.G1116R (on ENST00000636805 / NM_001376131.1; = p.G603R on NM_015237.4) | Missense Mutation (SNP) | VAF 32/454 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.08); catalogued as COSV64885793; called by muse, mutect2
- CA9 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.712); catalogued as rs1418623988; called by muse, mutect2, varscan2
- CARD6 | c.3018G>T p.Q1006H | Missense Mutation (SNP) | VAF 32/484 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as rs878932568; called by muse, mutect2
- CCDC103 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 66/656 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV53652020; called by muse, mutect2
- CCDC136 | c.2744C>T p.P915L | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1330524936; called by muse, mutect2
- CCDC150 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 79/259 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as rs753442017; called by muse, mutect2, varscan2
- CD48 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 54/485 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs1433255876; called by muse, mutect2, varscan2
- CDH6 | c.256G>T p.G86* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as COSV54080249, COSV99418452; called by muse, varscan2
- CDH9 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 19/496 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50374751; called by muse, mutect2
- CDK5RAP1 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 79/760 reads (10%) | catalogued as rs769926209; called by muse, mutect2, varscan2
- CDYL2 | c.441G>C p.M147I | Missense Mutation (SNP) | VAF 28/325 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV101629560; called by muse, mutect2
- CELF3 | c.1348C>A p.R450S | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1198353062, COSV51886111; called by muse, mutect2, varscan2
- CFHR5 | c.668G>C p.R223T | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV56818634; called by muse, mutect2
- CNGA3 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 51/450 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as COSV55623747; called by muse, mutect2, varscan2
- CNGB3 | c.939C>A p.C313* | Nonsense Mutation (SNP) | VAF 26/369 reads (7%) | catalogued as COSV60697103; called by muse, mutect2
- COG7 | c.1391C>G p.A464G | Missense Mutation (SNP) | VAF 33/536 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.782); catalogued as rs1339781797, COSV100207674; called by muse, mutect2
- COL23A1 | c.1342G>A p.G448S | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1465733269, COSV101179822; called by muse, mutect2
- COL6A3 | c.3062C>A p.P1021Q | Missense Mutation (SNP) | VAF 26/606 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV55102479; called by muse, mutect2
- CORO2B | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV55955707; called by mutect2, varscan2
- CRYGA | c.471G>T p.W157C | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1052600801; called by muse, mutect2
- CSH2 | c.514T>A p.F172I | Missense Mutation (SNP) | VAF 75/1097 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV61080529; called by muse, mutect2
- CSMD1 | c.10510G>T p.G3504W (on ENST00000520002; = p.G3503W on NM_033225.6) | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59283215, COSV59302811; called by muse, mutect2
- CSMD2 | c.9832C>A p.L3278M | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.786); catalogued as COSV53882668; called by muse, mutect2
- CSMD3 | c.10480G>T p.V3494L (on ENST00000297405 / NM_001363185.1; = p.V3325L on NM_052900.3) | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs866015702, COSV52311928; called by muse, mutect2
- CSMD3 | c.2047C>A p.R683S (on ENST00000297405 / NM_001363185.1; = p.R579S on NM_052900.3) | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs1266203286, COSV52185681; called by muse, mutect2
- CTU1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 16/422 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1325060563, COSV104436693; called by muse, mutect2
- DMD | c.7853A>T p.K2618M | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100626808; called by muse, mutect2
- DMRTB1 | c.800C>A p.P267Q | Missense Mutation (SNP) | VAF 54/490 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV101008273; called by muse, varscan2
- DOCK3 | c.828A>T p.T276= | Splice Region (SNP) | VAF 15/249 reads (6%) | catalogued as rs1262703597; called by muse, mutect2
- ELAPOR2 | c.1180G>T p.D394Y (on ENST00000450689 / NM_001142749.3; = p.D227Y on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs1294318508; called by muse, mutect2
- ELAVL4 | c.131G>T p.S44I | Missense Mutation (SNP) | VAF 22/586 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV63914785; called by muse, mutect2
- ERICH3 | c.458C>A p.P153Q | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1168284622, COSV100443750, COSV58616468; called by muse, mutect2
- EVA1A | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52063097; called by mutect2, varscan2
- EXO5 | c.602G>T p.R201M | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV56416075; called by muse, mutect2, varscan2
- F9 | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 22/576 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM035523; called by muse, mutect2
- FAM135B | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1459148940; called by muse, mutect2
- FAM47B | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 28/369 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV61454558; called by muse, mutect2
- FCRL1 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 48/516 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as COSV63826995; called by muse, mutect2
- FCRL2 | c.447C>G p.N149K | Missense Mutation (SNP) | VAF 76/830 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.102); catalogued as COSV63833055; called by muse, mutect2
- FLNC | c.6893C>A p.P2298H | Missense Mutation (SNP) | VAF 23/365 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1382734231; called by muse, mutect2
- FOXD4L1 | c.860C>A p.A287E | Missense Mutation (SNP) | VAF 86/1497 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.338); catalogued as COSV52072805; called by muse, mutect2
- FRMD5 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.146); catalogued as rs373951833, COSV68720935; called by muse, mutect2, varscan2
- FSHR | c.1550G>T p.C517F | Missense Mutation (SNP) | VAF 13/303 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58628644; called by muse, mutect2
- FTHL17 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV63267307; called by muse, mutect2
- FUT4 | c.600dup p.R201Afs*3 | Frame Shift Ins (INS) | VAF 16/184 reads (9%) | catalogued as rs778031475; called by mutect2, pindel
- GJB1 | c.793C>A p.R265S | Missense Mutation (SNP) | VAF 32/592 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.286); catalogued as COSV100661238; called by muse, mutect2
- GLI3 | c.653C>A p.A218E | Missense Mutation (SNP) | VAF 46/810 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV67885452, COSV67888154; called by muse, mutect2
- GOLGB1 | c.7720G>T p.E2574* | Nonsense Mutation (SNP) | VAF 19/239 reads (8%) | catalogued as COSV61470120; called by muse, mutect2
- GRIA2 | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV52386086, COSV52389589; called by mutect2, varscan2
- GRIK2 | c.436T>A p.Y146N | Missense Mutation (SNP) | VAF 31/449 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); catalogued as COSV59732488; called by muse, mutect2
- GRM6 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs759897202; called by muse, mutect2
- GSX2 | c.764T>A p.V255E | Missense Mutation (SNP) | VAF 28/440 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58843077; called by muse, mutect2
- H4C13 | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); catalogued as COSV100138003; called by muse, mutect2
- HCN1 | c.2561G>T p.R854L | Missense Mutation (SNP) | VAF 17/398 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); catalogued as COSV57536554; called by muse, mutect2
- HDC | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 35/483 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.563); catalogued as COSV51083866; called by muse, mutect2
- HTRA4 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 49/732 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs965258466, COSV56759071; called by muse, mutect2
- ICE1 | c.3116C>T p.T1039I | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1448588600; called by muse, mutect2, varscan2
- IGHV4-59 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 62/1446 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); catalogued as rs565439859; called by muse, mutect2
- IL16 | c.1567G>T p.G523* | Nonsense Mutation (SNP) | VAF 18/240 reads (8%) | catalogued as COSV100267873; called by muse, mutect2
- IL17RD | c.1711C>A p.P571T | Missense Mutation (SNP) | VAF 15/343 reads (4%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as COSV56337259; called by muse, mutect2
- IL9R | c.1053C>A p.C351* | Nonsense Mutation (SNP) | VAF 23/195 reads (12%) | catalogued as rs139866056, COSV99729504; called by muse, mutect2, varscan2
- ILDR2 | c.1620G>T p.E540D | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1239391028; called by muse, mutect2
- INSRR | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.387); catalogued as COSV63871878; called by muse, mutect2, varscan2
- ITGA8 | c.1343C>A p.S448Y | Missense Mutation (SNP) | VAF 41/319 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV100959907; called by muse, mutect2, varscan2
- KATNIP | c.4012G>T p.V1338F | Missense Mutation (SNP) | VAF 34/357 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs141451373; called by muse, mutect2, varscan2
- KCNA6 | c.917C>G p.P306R | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99768921; called by muse, mutect2
- KCND2 | c.1655G>T p.S552I | Missense Mutation (SNP) | VAF 34/530 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.374); catalogued as COSV58602425; called by muse, mutect2
- KCNH1 | c.2515C>A p.R839S (on ENST00000271751 / NM_172362.3; = p.R812S on NM_002238.4) | Missense Mutation (SNP) | VAF 29/397 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.106); catalogued as COSV55068411; called by muse, mutect2
- KCNH6 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 64/908 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.263); catalogued as COSV59001363, COSV59008071; called by muse, mutect2
- KDR | c.4042G>T p.G1348W | Missense Mutation (SNP) | VAF 32/480 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV55763675; called by muse, mutect2
- KIAA0586 | c.1493A>G p.D498G (on ENST00000619416 / NM_001244190.2; = p.D513G on NM_014749.5) | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as rs796052129, CM158384; called by muse, mutect2
- KIF13B | c.5125G>T p.V1709L | Missense Mutation (SNP) | VAF 54/792 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as rs1230906498; called by muse, mutect2
- KIR2DL1 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 26/343 reads (8%) | catalogued as COSV52410003; called by muse, mutect2
- KRT5 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV99358203; called by muse, mutect2
- KRT5 | c.67A>G p.I23V | Missense Mutation (SNP) | VAF 13/289 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1463762295; called by muse, mutect2
- KRTAP19-2 | c.158A>T p.*53Lext*12 | Nonstop Mutation (SNP) | VAF 28/272 reads (10%) | catalogued as rs1159530386; called by muse, mutect2
- LAMA5 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53354884; called by muse, mutect2, varscan2
- LHX1 | c.1014C>A p.S338R | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as rs759116419; called by muse, mutect2
- LILRB3 | c.1475C>A p.T492N (on ENST00000346401; = p.T480N on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/434 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as COSV54447791; called by muse, mutect2
- LNX1 | c.1351G>A p.A451T (on ENST00000263925 / NM_001126328.3; = p.A355T on NM_032622.2) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.893); catalogued as COSV55785838; called by muse, mutect2
- LRP1B | c.9061G>C p.D3021H | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV67199554; called by muse, mutect2
- LVRN | c.2939C>A p.A980D | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV63497350, COSV63497879; called by muse, mutect2
- MARCHF8 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 39/662 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as rs1564460961; called by muse, mutect2
- MAT1A | c.980C>G p.P327R | Missense Mutation (SNP) | VAF 66/1228 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64745345; called by muse, mutect2
- MBL2 | c.718del p.H240Ifs*34 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | catalogued as COSV64759286, COSV64759557; called by mutect2, pindel
- MCOLN2 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99393547; called by muse, mutect2, varscan2
- MED13L | c.4484A>G p.N1495S | Missense Mutation (SNP) | VAF 28/792 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.219); catalogued as rs1005060536; called by muse, mutect2
- MSR1 | c.179T>A p.V60E | Missense Mutation (SNP) | VAF 44/595 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs763359718; called by muse, mutect2
- MTUS2 | c.2902C>A p.P968T | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs979607407; called by muse, mutect2, varscan2
- MUC5B | c.8752C>A p.R2918S | Missense Mutation (SNP) | VAF 10/303 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV71595440; called by muse, mutect2
- MYO7B | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 31/458 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs557534259; called by muse, mutect2
- NR4A2 | c.1705G>T p.G569W | Missense Mutation (SNP) | VAF 24/578 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59894582; called by muse, mutect2
- NRXN1 | c.3272C>G p.S1091* | Nonsense Mutation (SNP) | VAF 20/165 reads (12%) | catalogued as COSV58434140; called by muse, mutect2, varscan2
- OR10A7 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 20/377 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.333); catalogued as COSV100406610; called by muse, mutect2
- OR1M1 | c.588G>T p.R196S | Missense Mutation (SNP) | VAF 36/547 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV70037427; called by muse, mutect2
- OR2W3 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 38/532 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV100831609; called by muse, mutect2
- OR5L2 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1244719905, COSV65724308; called by muse, mutect2
- OR7G2 | c.788G>C p.G263A | Missense Mutation (SNP) | VAF 31/318 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.652); catalogued as COSV100560520, COSV59687505; called by muse, mutect2
- PACRG | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61297638; called by muse, mutect2
- PCDH15 | c.1456G>T p.G486C | Missense Mutation (SNP) | VAF 30/571 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57290777, COSV57399900; called by muse, mutect2
- PCDHGA5 | c.1726G>T p.E576* | Nonsense Mutation (SNP) | VAF 32/550 reads (6%) | catalogued as COSV54045738; called by muse, mutect2
- PCDHGB3 | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 36/413 reads (9%) | catalogued as COSV53900021; called by muse, mutect2
- PCDHGB3 | c.1019A>G p.E340G | Missense Mutation (SNP) | VAF 36/405 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV53958476; called by muse, mutect2
- PDZRN3 | c.1783G>C p.A595P | Missense Mutation (SNP) | VAF 38/488 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV99732903; called by muse, mutect2
- PI4KB | c.1325G>C p.R442P (on ENST00000368873 / NM_001369623.1; = p.R454P on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/609 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV55016075; called by muse, mutect2
- PIEZO2 | c.5872C>A p.P1958T | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV53292594; called by muse, mutect2
- PKHD1 | c.2134G>T p.V712L | Missense Mutation (SNP) | VAF 40/588 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV61880538; called by muse, mutect2
- PLCH1 | c.3676C>T p.H1226Y (on ENST00000340059 / NM_001130960.2; = p.H1218Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.04); catalogued as COSV58195715; called by muse, mutect2
- PLG | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 20/260 reads (8%) | catalogued as COSV99805112; called by muse, mutect2
- POLQ | c.5362G>C p.G1788R | Missense Mutation (SNP) | VAF 29/372 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV51746492; called by muse, mutect2
- PSG1 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 27/362 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as rs1041096500, COSV54952596; called by muse, mutect2
- PTCHD4 | c.626A>G p.H209R | Missense Mutation (SNP) | VAF 44/688 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs774829925; called by muse, mutect2
- PTGR1 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV53030634; called by muse, mutect2
- PXDNL | c.2231C>A p.A744E | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62496716; called by muse, mutect2, varscan2
- RBM19 | c.2559-1G>A p.X853_splice | Splice Site (SNP) | VAF 20/333 reads (6%) | catalogued as COSV99028310; called by muse, mutect2
- RBP3 | c.3628G>T p.G1210W | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555212077; called by muse, mutect2, varscan2
- RHOBTB1 | c.1462A>T p.T488S | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as rs1444465988; called by muse, mutect2
- RIN2 | c.349G>T p.V117L (on ENST00000255006 / NM_001242581.1; = p.V68L on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/494 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs766657277, COSV54791566; called by muse, mutect2, varscan2
- RP1L1 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1316164291; called by muse, mutect2
- RYR2 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV63672605; called by muse, mutect2
- RYR2 | c.12292G>T p.V4098F | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as COSV63661279, COSV63692480; called by muse, mutect2
- SCN1A | c.5170G>T p.A1724S (on ENST00000303395 / NM_001202435.3; = p.A1713S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM1211399; called by muse, mutect2
- SCN1B | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 35/768 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs1034016541, COSV99386674; called by muse, mutect2
- SDF2L1 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.401); catalogued as COSV99963678; called by muse, mutect2
- SDK2 | c.4838C>A p.P1613Q | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV66183043; called by muse, mutect2, varscan2
- SDK2 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 44/484 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV66199726; called by muse, mutect2
- SEC11C | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1427255673; called by muse, mutect2, varscan2
- SERPINA9 | c.447G>T p.L149F | Missense Mutation (SNP) | VAF 33/886 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1223572546; called by muse, mutect2
- SHOX | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 50/561 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.36); catalogued as CM074519; called by muse, mutect2
- SIGLEC8 | c.351G>T p.R117S | Missense Mutation (SNP) | VAF 46/870 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.06); catalogued as COSV58473124; called by muse, mutect2
- SLC39A12 | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99075541; called by muse, mutect2
- SLC4A4 | c.1280G>T p.G427V (on ENST00000264485 / NM_001098484.3; = p.G383V on NM_003759.4) | Missense Mutation (SNP) | VAF 34/527 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV52619639; called by muse, mutect2
- SLC6A5 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 42/567 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs763873675; called by muse, mutect2
- SLIT1 | c.4439C>G p.T1480R | Missense Mutation (SNP) | VAF 29/334 reads (9%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.615); catalogued as COSV56581313; called by muse, mutect2
- SLITRK3 | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 17/420 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.527); catalogued as rs1369609178; called by muse, mutect2
- SLITRK4 | c.792G>T p.M264I | Missense Mutation (SNP) | VAF 17/432 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as rs781921529; called by muse, mutect2
- SORCS1 | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as rs1234805101; called by muse, mutect2
- SPOCK1 | c.1039C>A p.Q347K | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56444090; called by muse, mutect2
- SPTA1 | c.6745G>C p.G2249R | Missense Mutation (SNP) | VAF 40/269 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1441724207, COSV63755128; called by muse, mutect2, varscan2
- SUGP1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 32/366 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1407291543; called by muse, mutect2
- TBC1D9 | c.2929G>T p.G977C | Missense Mutation (SNP) | VAF 30/346 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101464346; called by muse, mutect2
- TCF4 | c.1241G>A p.G414D | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as CD120298; called by muse, mutect2
- TCF4 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 24/535 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV100608891; called by muse, mutect2
- TDO2 | c.1067+1G>C p.X356_splice | Splice Site (SNP) | VAF 14/199 reads (7%) | catalogued as rs113632610; called by muse, mutect2
- TECRL | c.140G>T p.R47I | Missense Mutation (SNP) | VAF 30/549 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1253517369; called by muse, mutect2
- TENM3 | c.5885A>T p.D1962V | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV69308410; called by muse, mutect2
- TGM5 | c.1783C>T p.R595C (on ENST00000220420 / NM_201631.4; = p.R513C on NM_004245.4) | Missense Mutation (SNP) | VAF 33/430 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs777999621, COSV55010503; called by muse, mutect2
- TLR4 | c.343C>A p.Q115K (on ENST00000355622 / NM_138554.5; = p.Q75K on NM_003266.4) | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV62923829; called by muse, mutect2
- TMPRSS11F | c.244A>G p.R82G | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.331); catalogued as rs1240478142; called by muse, mutect2
- TRAV12-3 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 15/276 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs867729580; called by muse, mutect2
- TRIM77 | c.1059G>T p.W353C | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV101242067; called by muse, mutect2
- TTLL3 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 33/406 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as rs1251103992; called by muse, mutect2
- TTN | c.17582G>A p.C5861Y (on ENST00000591111; = p.C4934Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/505 reads (10%) | PolyPhen probably damaging (0.998); catalogued as rs760469804; called by muse, mutect2, varscan2
- TTN | c.10127C>T p.S3376L (on ENST00000591111; = p.S3330L on NM_003319.4) | Missense Mutation (SNP) | VAF 28/331 reads (8%) | PolyPhen benign (0.123); catalogued as rs781368765, COSV59980318; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.5514G>T p.K1838N (on ENST00000591111; = p.K1792N on NM_003319.4) | Missense Mutation (SNP) | VAF 30/630 reads (5%) | PolyPhen probably damaging (0.997); catalogued as rs1172907334; called by muse, mutect2
- TTN | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 48/345 reads (14%) | PolyPhen benign (0.029); catalogued as rs1385595780; called by muse, mutect2, varscan2
- UNC79 | c.1997T>C p.M666T (on ENST00000393151 / NM_001346218.2; = p.M489T on NM_020818.5) | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs754152834; called by muse, mutect2
- VSTM2A | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.966); catalogued as COSV101281081; called by muse, mutect2
- ZNF530 | c.1196G>T p.R399I | Missense Mutation (SNP) | VAF 26/441 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs893795043, COSV60531473; called by muse, mutect2
- ZNF629 | c.1543G>T p.V515L | Missense Mutation (SNP) | VAF 38/304 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV52698817; called by muse, mutect2, varscan2
- ZNF716 | c.546G>C p.K182N | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV101348735; called by muse, mutect2
- ZNF98 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100757545; called by muse, mutect2
- A1BG | c.539A>T p.Y180F | Missense Mutation (SNP) | VAF 79/744 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCA12 | c.7370C>G p.T2457S (on ENST00000272895 / NM_173076.3; = p.T2139S on NM_015657.3) | Missense Mutation (SNP) | VAF 24/519 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.325); called by muse, mutect2
- ABCA2 | c.3731G>T p.G1244V (on ENST00000614293; = p.G1214V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCB1 | c.2065-2A>T p.X689_splice | Splice Site (SNP) | VAF 17/272 reads (6%) | called by muse, mutect2
- ABCC12 | c.2369G>T p.G790V | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AC011005.1 | c.910A>T p.N304Y | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- ACOD1 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.893); called by muse, mutect2
- ADAMTS2 | c.832G>T p.V278L | Missense Mutation (SNP) | VAF 64/890 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAMTSL1 | c.1723C>A p.Q575K | Missense Mutation (SNP) | VAF 52/662 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.338); called by muse, mutect2
- ADAMTSL4 | c.1699G>T p.G567W | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADCY10 | c.3236G>T p.G1079V | Missense Mutation (SNP) | VAF 38/538 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- ADCY8 | c.2798C>T p.A933V | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2
- ADGRB2 | c.4441C>G p.H1481D (on ENST00000373658 / NM_001364857.2; = p.H1480D on NM_001294335.2) | Missense Mutation (SNP) | VAF 42/614 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- AFAP1L1 | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2
- AGT | c.1269+1G>C p.X423_splice | Splice Site (SNP) | VAF 46/902 reads (5%) | called by muse, mutect2
- AKAP11 | c.4308A>T p.K1436N | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.078); called by muse, mutect2
- ALB | c.168G>T p.Q56H | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- ALG13 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 18/403 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.33); called by muse, mutect2
- ALPK2 | c.3576G>T p.R1192S | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AMER3 | c.1054C>A p.L352I | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- AMPH | c.74T>A p.L25H | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANK1 | c.4837C>A p.P1613T | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2
- ANKFY1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 38/520 reads (7%) | called by muse, mutect2
- ANKRD33B | c.1258G>T p.G420C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ANKRD36C | c.4863A>T p.R1621S | Missense Mutation (SNP) | VAF 45/492 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.234); called by muse, mutect2
- AQP8 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2
- ARAP2 | c.3543G>T p.Q1181H | Missense Mutation (SNP) | VAF 42/504 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.961); called by muse, mutect2
- ARHGEF11 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 39/553 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASTN1 | c.122C>A p.T41K | Missense Mutation (SNP) | VAF 50/598 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ASXL3 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATN1 | c.2494G>C p.E832Q | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ATRNL1 | c.1889G>T p.G630V | Missense Mutation (SNP) | VAF 23/432 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2
- B3GNT2 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 23/507 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.435); called by muse, mutect2
- BICRAL | c.2126A>T p.Q709L | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.03); called by muse, mutect2
- BMP5 | c.1208A>G p.Q403R | Missense Mutation (SNP) | VAF 31/492 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BMT2 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.119); called by muse, mutect2
- BOC | c.2616C>A p.F872L | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BTBD16 | c.60C>G p.N20K | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- C10orf71 | c.2722C>G p.P908A | Missense Mutation (SNP) | VAF 29/529 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.12); called by muse, mutect2
- C16orf78 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 46/511 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- C4orf54 | c.3280G>T p.D1094Y | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- C6 | c.2414C>A p.T805K | Missense Mutation (SNP) | VAF 34/462 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.259); called by muse, mutect2
- CACNA1E | c.4407C>A p.Y1469* | Nonsense Mutation (SNP) | VAF 48/566 reads (8%) | called by muse, mutect2
- CACNA1F | c.346C>G p.P116A | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- CACNA1I | c.1629del p.A544Pfs*104 | Frame Shift Del (DEL) | VAF 19/139 reads (14%) | called by mutect2, pindel, varscan2
- CACNB4 | c.236A>T p.Q79L | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- CAD | c.6347G>T p.R2116L | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- CAGE1 | c.1309C>A p.Q437K (on ENST00000512086; = p.Q301K on NM_205864.3) | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.242); called by muse, mutect2
- CAPN8 | c.1798T>A p.F600I | Missense Mutation (SNP) | VAF 15/428 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2
- CASR | c.1921T>A p.W641R (on ENST00000490131; = p.W718R on NM_000388.4) | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2
- CBLIF | c.536C>G p.A179G | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2
- CCDC60 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2
- CCNA1 | c.751C>A p.L251M | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2
- CD1C | c.990G>T p.Q330H | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CD37 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- CD40 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 82/671 reads (12%) | called by muse, mutect2, varscan2
- CDH8 | c.1906+1G>T p.X636_splice | Splice Site (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- CDH8 | c.344C>G p.T115S | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2
- CDH9 | c.1034T>C p.L345S | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CDH9 | c.966G>T p.K322N | Missense Mutation (SNP) | VAF 51/504 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CDRT15L2 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 18/359 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- CEACAM20 | c.1708G>C p.V570L | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2
- CEP112 | c.2049G>T p.K683N | Missense Mutation (SNP) | VAF 23/357 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2
- CEP350 | c.8965G>T p.E2989* | Nonsense Mutation (SNP) | VAF 22/349 reads (6%) | called by muse, mutect2
- CERCAM | c.1300G>T p.V434L | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CES5A | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 22/262 reads (8%) | called by muse, mutect2
- CHAT | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.076); called by muse, mutect2
- CHRM2 | c.190A>T p.S64C | Missense Mutation (SNP) | VAF 25/690 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRM3 | c.431G>T p.W144L | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLDN14 | c.142A>T p.K48* | Nonsense Mutation (SNP) | VAF 89/832 reads (11%) | called by muse, mutect2, varscan2
- CLEC9A | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.14); called by muse, mutect2
- CLSPN | c.1601G>T p.R534L | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CNDP2 | c.1249A>T p.S417C | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2
- CNP | c.133A>T p.T45S | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- CNTN4 | c.2398+1G>C p.X800_splice | Splice Site (SNP) | VAF 28/428 reads (7%) | called by muse, mutect2
- CNTNAP2 | c.3599C>A p.S1200* | Nonsense Mutation (SNP) | VAF 30/646 reads (5%) | called by muse, mutect2
- CNTNAP5 | c.1374G>T p.R458S | Missense Mutation (SNP) | VAF 17/452 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- COBLL1 | c.3064G>T p.A1022S (on ENST00000392717; = p.A984S on NM_014900.5) | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL1A1 | c.818T>C p.L273S | Missense Mutation (SNP) | VAF 52/1076 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL1A2 | c.2519C>A p.P840H | Missense Mutation (SNP) | VAF 50/771 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2
- COL22A1 | c.3110G>T p.G1037V | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL22A1 | c.3109G>T p.G1037C | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL3A1 | c.2684C>G p.P895R | Missense Mutation (SNP) | VAF 180/488 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- COL6A5 | c.6578A>T p.Q2193L (on ENST00000312481; = p.Q2189L on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- COPA | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 18/294 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.264); called by muse, mutect2
- CPN2 | c.222C>A p.N74K | Missense Mutation (SNP) | VAF 13/261 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- CPZ | c.1030G>T p.D344Y (on ENST00000360986 / NM_001014447.3; = p.D333Y on NM_003652.3) | Missense Mutation (SNP) | VAF 15/225 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CRB1 | c.1596T>A p.F532L | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.318); called by muse, mutect2
- CREBRF | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRNN | c.754A>T p.R252* | Nonsense Mutation (SNP) | VAF 55/856 reads (6%) | called by muse, mutect2
- CRYBB1 | c.32C>A p.A11D | Missense Mutation (SNP) | VAF 28/509 reads (6%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.1); called by muse, mutect2
- CSMD3 | c.10886G>T p.S3629I (on ENST00000297405 / NM_001363185.1; = p.S3460I on NM_052900.3) | Missense Mutation (SNP) | VAF 25/396 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CSMD3 | c.7268G>T p.C2423F (on ENST00000297405 / NM_001363185.1; = p.C2319F on NM_052900.3) | Missense Mutation (SNP) | VAF 26/480 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); called by muse, mutect2
- CTAG2 | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- CTNND2 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 39/275 reads (14%) | called by muse, mutect2, varscan2
- CUBN | c.3686C>A p.P1229Q | Missense Mutation (SNP) | VAF 63/614 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- CUL4B | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2
- CYP11B2 | c.784T>G p.C262G | Missense Mutation (SNP) | VAF 55/1012 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- CYP26B1 | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 65/857 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- CYP3A7 | c.71+1G>A p.X24_splice | Splice Site (SNP) | VAF 27/888 reads (3%) | called by muse, mutect2
- DACH2 | c.771A>G p.T257= | Splice Region (SNP) | VAF 15/140 reads (11%) | called by muse, varscan2
- DACH2 | c.829G>T p.G277* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- DCAF8L2 | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 36/567 reads (6%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); called by muse, mutect2
- DCC | c.2229G>T p.M743I | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.152); called by muse, mutect2
- DCHS1 | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- DDC | c.1002G>T p.K334N | Missense Mutation (SNP) | VAF 41/1139 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2
- DDIAS | c.2608C>T p.Q870* | Nonsense Mutation (SNP) | VAF 19/152 reads (13%) | called by muse, mutect2, varscan2
- DEPTOR | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); called by muse, mutect2
- DMD | c.4344G>T p.Q1448H | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- DNAH3 | c.1647A>T p.K549N | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- DNAI2 | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 57/690 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2
- DNM2 | c.279C>G p.D93E | Missense Mutation (SNP) | VAF 42/756 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.069); called by muse, mutect2
- DOP1A | c.5371G>T p.A1791S | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.985); called by muse, mutect2
- DST | c.21694G>T p.D7232Y (on ENST00000361203 / NM_001374722.1; = p.D4929Y on NM_015548.5) | Missense Mutation (SNP) | VAF 12/223 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DST | c.17512G>C p.E5838Q (on ENST00000361203 / NM_001374722.1; = p.E3535Q on NM_015548.5) | Missense Mutation (SNP) | VAF 17/402 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DTHD1 | c.2183G>T p.C728F (on ENST00000456874; = p.C563F on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/423 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- DTWD1 | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.244); called by muse, mutect2
- DYRK3 | c.1339G>T p.G447C | Missense Mutation (SNP) | VAF 44/462 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ECM1 | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 38/487 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2
- EDAR | c.137A>T p.E46V | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EFCAB12 | c.1582G>C p.A528P | Missense Mutation (SNP) | VAF 32/435 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.182); called by muse, mutect2
- EGLN3 | c.185C>A p.A62E | Missense Mutation (SNP) | VAF 32/331 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2
- ELF4 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 28/672 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.125); called by muse, mutect2
- EMILIN1 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | called by muse, varscan2
- EPHA6 | c.2110G>T p.D704Y (on ENST00000389672 / NM_001080448.3; = p.D96Y on NM_173655.4) | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- ESPNL | c.2771C>T p.A924V | Missense Mutation (SNP) | VAF 21/368 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.145); called by muse, mutect2
- ESRRB | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- EVC2 | c.2891C>A p.A964E | Missense Mutation (SNP) | VAF 57/1086 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- EXOC4 | c.2233A>T p.T745S | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- F11 | c.956A>T p.K319I | Missense Mutation (SNP) | VAF 26/405 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2
- F13B | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 37/528 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); called by muse, mutect2
- F2 | c.938G>T p.G313V | Missense Mutation (SNP) | VAF 59/710 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- FAM172A | c.272A>T p.H91L | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.996); called by muse, mutect2
- FANCC | c.376A>T p.R126* | Nonsense Mutation (SNP) | VAF 22/291 reads (8%) | called by muse, mutect2
- FAT4 | c.13492G>T p.E4498* | Nonsense Mutation (SNP) | VAF 42/620 reads (7%) | called by muse, mutect2
- FBN1 | c.8077G>T p.G2693C | Missense Mutation (SNP) | VAF 48/678 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2
- FBN1 | c.8076G>C p.M2692I | Missense Mutation (SNP) | VAF 46/684 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- FBN3 | c.8372G>T p.G2791V | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- FBN3 | c.6184+1del p.X2062_splice | Splice Site (DEL) | VAF 12/130 reads (9%) | called by mutect2, pindel
- FGF4 | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- FGF5 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 17/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FRG2C | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 28/835 reads (3%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.542); called by muse, mutect2
- FTHL17 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 35/436 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FUNDC2 | c.68A>G p.Y23C | Missense Mutation (SNP) | VAF 15/367 reads (4%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- FYB1 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 44/606 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.039); called by muse, mutect2
- FZD8 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 21/321 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2
- GABRA2 | c.1147G>T p.V383F | Missense Mutation (SNP) | VAF 17/388 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.26); called by muse, mutect2
- GABRA6 | c.107T>A p.L36Q | Missense Mutation (SNP) | VAF 24/577 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GDF1 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- GDF1 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- GDPD4 | c.625-1G>T p.X209_splice | Splice Site (SNP) | VAF 11/215 reads (5%) | called by muse, mutect2
- GGNBP2 | c.1966C>T p.Q656* | Nonsense Mutation (SNP) | VAF 18/335 reads (5%) | called by muse, mutect2
- GIT2 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- GJC3 | c.538T>C p.C180R | Missense Mutation (SNP) | VAF 30/628 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLUL | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 54/578 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- GOLGA4 | c.5443C>A p.H1815N | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GPC4 | c.200G>C p.C67S | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPR101 | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 18/299 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.182); called by muse, mutect2
- GRID1 | c.1715C>A p.A572D | Missense Mutation (SNP) | VAF 64/931 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- GRID1 | c.1004A>G p.H335R | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.307); called by muse, mutect2
- GRIN2B | c.3901C>A p.Q1301K | Missense Mutation (SNP) | VAF 50/624 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GSG1 | c.1001C>A p.S334Y (on ENST00000651961 / NM_001080555.4; = p.S298Y on NM_153823.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- HAS2 | c.1514C>A p.S505* | Nonsense Mutation (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- HCCS | c.74G>T p.C25F | Missense Mutation (SNP) | VAF 56/736 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HECW2 | c.4076G>T p.W1359L | Missense Mutation (SNP) | VAF 67/379 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HELZ2 | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2
- HGFAC | c.1684G>C p.V562L | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2
- HIBADH | c.553G>C p.A185P | Missense Mutation (SNP) | VAF 20/436 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2
- HLX | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 20/477 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.767); called by muse, mutect2
- HMCN2 | c.11008G>T p.A3670S | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.216); called by muse, mutect2
- HMCN2 | c.12256G>C p.E4086Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.052); called by muse, mutect2
- HPSE2 | c.303G>T p.L101F | Missense Mutation (SNP) | VAF 46/657 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2
- HPX | c.233G>C p.S78T | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.105); called by muse, mutect2
- HSPG2 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 44/598 reads (7%) | called by muse, mutect2
- HTR1F | c.553T>A p.S185T | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HTR2A | c.251T>A p.V84E | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- HYDIN | c.14610G>C p.M4870I | Missense Mutation (SNP) | VAF 44/626 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- IGF1 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 33/408 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- IGHG3 | c.710C>A p.T237N | Missense Mutation (SNP) | VAF 28/688 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2
- IGKV1-27 | c.9G>T p.M3I | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); called by muse, mutect2
- IGLV1-36 | c.108G>T p.R36S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.021); called by muse, mutect2
- IGSF10 | c.6452A>T p.K2151M | Missense Mutation (SNP) | VAF 48/433 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IGSF10 | c.6451A>T p.K2151* | Nonsense Mutation (SNP) | VAF 49/433 reads (11%) | called by muse, mutect2, varscan2
- IL21R | c.272A>C p.D91A | Missense Mutation (SNP) | VAF 73/878 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- IQSEC2 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.013); called by muse, mutect2
- IQSEC3 | c.2761A>T p.K921* (on ENST00000538872 / NM_001170738.2; = p.K618* on NM_015232.1) | Nonsense Mutation (SNP) | VAF 32/500 reads (6%) | called by muse, mutect2
- IRX1 | c.1319A>T p.D440V | Missense Mutation (SNP) | VAF 39/414 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2
- ITIH5 | c.1108+1G>T p.X370_splice | Splice Site (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- JADE1 | c.1964A>G p.D655G | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.071); called by muse, mutect2
- JPH2 | c.1185G>T p.K395N | Missense Mutation (SNP) | VAF 69/664 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- KCNA3 | c.1155G>T p.Q385H | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KCNB2 | c.284C>A p.A95D | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- KCNC4 | c.1493G>T p.R498L | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- KCNG4 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- KCNMA1 | c.728G>T p.W243L | Missense Mutation (SNP) | VAF 19/464 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.071); called by muse, mutect2
- KCNT2 | c.2275C>A p.P759T | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, mutect2
- KEL | c.2139G>T p.R713S | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2
- KIAA1109 | c.5377G>T p.V1793F | Missense Mutation (SNP) | VAF 22/540 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.054); called by muse, mutect2
- KIAA1614 | c.489G>T p.R163S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- KIR3DL1 | c.763C>A p.L255I | Missense Mutation (SNP) | VAF 36/597 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLK15 | c.725T>A p.V242D | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KNDC1 | c.2171C>A p.P724H | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- KRT5 | c.1267C>G p.L423V | Missense Mutation (SNP) | VAF 64/788 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.223); called by muse, mutect2
- KRT73 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 41/557 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2
- KRT76 | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- L1TD1 | c.1890G>T p.E630D | Missense Mutation (SNP) | VAF 29/361 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2
- LAMA2 | c.5065G>T p.A1689S | Missense Mutation (SNP) | VAF 26/531 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.099); called by muse, mutect2
- LAMC3 | c.2390C>A p.P797Q | Missense Mutation (SNP) | VAF 29/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LANCL2 | c.1051A>T p.S351C | Missense Mutation (SNP) | VAF 13/335 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); called by muse, mutect2
- LAPTM4A | c.527A>T p.K176M | Missense Mutation (SNP) | VAF 25/269 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LAPTM5 | c.302T>C p.M101T | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- LCT | c.3272A>G p.Y1091C | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LEFTY2 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 66/739 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- LEFTY2 | c.133A>T p.R45W | Missense Mutation (SNP) | VAF 27/386 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2
- LORICRIN | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 21/215 reads (10%) | PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LOXHD1 | c.5755C>A p.L1919M (on ENST00000642948; = p.L1857M on NM_144612.7) | Missense Mutation (SNP) | VAF 47/424 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LOXHD1 | c.2302G>T p.G768C | Missense Mutation (SNP) | VAF 23/443 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2
- LPCAT4 | c.1094A>T p.Q365L | Missense Mutation (SNP) | VAF 44/534 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.3); called by muse, mutect2
- LRRC4C | c.709G>T p.G237C | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- LTK | c.2347G>T p.D783Y | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LYPD3 | c.857A>T p.H286L | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2
- MAB21L3 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2
- MAGEB16 | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2
- MAP1B | c.4727C>A p.A1576D | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MARCO | c.173C>A p.A58D | Missense Mutation (SNP) | VAF 38/484 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2
- MASP1 | c.1687G>C p.V563L | Missense Mutation (SNP) | VAF 38/345 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MASP1 | c.1090+2T>C p.X364_splice | Splice Site (SNP) | VAF 28/440 reads (6%) | called by muse, mutect2
- MED12 | c.940A>T p.S314C | Missense Mutation (SNP) | VAF 23/271 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); called by muse, mutect2
- MEOX2 | c.279C>A p.H93Q | Missense Mutation (SNP) | VAF 21/556 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); called by muse, mutect2
- MEPE | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.878); called by muse, mutect2
- METTL14 | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEX3D | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- MINPP1 | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 27/320 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.268); called by muse, mutect2
- MKKS | c.1661A>G p.E554G | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- MOCS1 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MRC1 | c.1310G>T p.W437L | Missense Mutation (SNP) | VAF 46/734 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MS4A18 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 20/205 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.137); called by muse, mutect2
- MS4A6A | c.254C>G p.S85C | Missense Mutation (SNP) | VAF 26/522 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- MS4A6E | c.281C>G p.T94S | Missense Mutation (SNP) | VAF 30/560 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.009); called by muse, mutect2
- MSH4 | c.2345T>A p.L782Q | Missense Mutation (SNP) | VAF 26/363 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MTHFR | c.1894C>T p.L632F | Missense Mutation (SNP) | VAF 47/567 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2
- MUC16 | c.26260C>A p.P8754T | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2
- MYBPC1 | c.3212G>A p.R1071K (on ENST00000550270 / NM_206820.2; = p.R1078K on NM_002465.4) | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- MYF6 | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 35/716 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH13 | c.5017G>T p.E1673* | Nonsense Mutation (SNP) | VAF 28/251 reads (11%) | called by muse, mutect2, varscan2
- MYH13 | c.3752G>C p.R1251T | Missense Mutation (SNP) | VAF 19/283 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2
- MYH2 | c.3974T>G p.L1325R | Missense Mutation (SNP) | VAF 28/653 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- MYH2 | c.805+2T>A p.X269_splice | Splice Site (SNP) | VAF 20/324 reads (6%) | called by muse, mutect2
- MYO15A | c.8602-1G>C p.X2868_splice | Splice Site (SNP) | VAF 50/689 reads (7%) | called by muse, mutect2
- MYO18B | c.7550C>G p.S2517C | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO1A | c.542-1G>T p.X181_splice | Splice Site (SNP) | VAF 32/367 reads (9%) | called by muse, mutect2
- MYO9A | c.1759A>T p.I587L | Missense Mutation (SNP) | VAF 28/444 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2
- NAALAD2 | c.1133C>A p.P378Q | Missense Mutation (SNP) | VAF 20/293 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NAALADL1 | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 44/627 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.101); called by muse, mutect2
- NAP1L3 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 17/286 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.028); called by muse, mutect2
- NAV2 | c.2261C>A p.A754D (on ENST00000396087 / NM_001244963.2; = p.A731D on NM_145117.5) | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NBEA | c.2179G>A p.V727M | Missense Mutation (SNP) | VAF 16/355 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- NEXN | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- NF1 | c.4192C>T p.P1398S (on ENST00000358273 / NM_001042492.3; = p.P1377S on NM_000267.3) | Missense Mutation (SNP) | VAF 22/437 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); called by muse, mutect2
- NGEF | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.243); called by muse, mutect2
- NID2 | c.3482T>A p.V1161D | Missense Mutation (SNP) | VAF 30/384 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2
- NLRP12 | c.387C>G p.Y129* | Nonsense Mutation (SNP) | VAF 56/897 reads (6%) | called by muse, mutect2
- NLRP13 | c.1857G>T p.W619C | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); called by muse, mutect2
- NLRP3 | c.1534T>G p.C512G | Missense Mutation (SNP) | VAF 39/462 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- NPAS3 | c.223G>T p.A75S (on ENST00000356141 / NM_001164749.2; = p.A45S on NM_022123.3) | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); called by muse, mutect2
- NPAS4 | c.602C>A p.P201Q | Missense Mutation (SNP) | VAF 52/680 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.062); called by muse, mutect2
- NPFFR1 | c.133A>G p.M45V | Missense Mutation (SNP) | VAF 36/624 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- NPHP1 | c.635A>G p.E212G | Missense Mutation (SNP) | VAF 56/580 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- NPHS1 | c.275-2A>T p.X92_splice | Splice Site (SNP) | VAF 35/586 reads (6%) | called by muse, mutect2
- NRXN1 | c.1241T>C p.F414S | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2
- NSUN6 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- NXPE3 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- OBSCN | c.3299A>T p.Q1100L | Missense Mutation (SNP) | VAF 34/732 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2
- OLFM3 | c.686T>A p.V229D (on ENST00000338858 / NM_001288821.1; = p.V209D on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/372 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- OR2C3 | c.724T>G p.C242G | Missense Mutation (SNP) | VAF 48/652 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- OR2G2 | c.385G>C p.V129L | Missense Mutation (SNP) | VAF 43/498 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2
- OR4B1 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.629); called by muse, mutect2
- OR4K14 | c.215T>G p.M72R | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2
- OR5AR1 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 22/426 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- OR5B21 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.013); called by muse, mutect2
- OR5B3 | c.319A>C p.T107P | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- OR8B12 | c.308del p.F103Sfs*60 | Frame Shift Del (DEL) | VAF 26/257 reads (10%) | called by mutect2, pindel
- PANX3 | c.578A>T p.E193V | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH15 | c.5058G>C p.K1686N (on ENST00000644397 / NM_001354429.2; = p.K1628N on NM_001142771.2) | Missense Mutation (SNP) | VAF 64/856 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.714); called by muse, mutect2
- PCDH15 | c.4761A>C p.K1587N | Missense Mutation (SNP) | VAF 20/474 reads (4%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.045); called by muse, mutect2
- PCDH7 | c.1561C>A p.L521M | Missense Mutation (SNP) | VAF 30/672 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH7 | c.2544G>T p.E848D | Missense Mutation (SNP) | VAF 34/542 reads (6%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.98); called by muse, mutect2
- PCDH9 | c.1664A>C p.Q555P | Missense Mutation (SNP) | VAF 11/201 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2
- PCDHB11 | c.1639G>T p.V547L | Missense Mutation (SNP) | VAF 68/1414 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- PCDHGA2 | c.2263C>T p.H755Y | Missense Mutation (SNP) | VAF 56/744 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2
- PCDHGA4 | c.1722C>A p.S574R | Missense Mutation (SNP) | VAF 30/472 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); called by muse, mutect2
- PCOLCE2 | c.1163G>T p.G388V | Missense Mutation (SNP) | VAF 28/540 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- PDCD10 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 38/510 reads (7%) | called by muse, mutect2
- PDZRN3 | c.1456G>T p.A486S | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.353); called by muse, mutect2
- PGAM4 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 24/784 reads (3%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.532); called by muse, mutect2
- PGLYRP3 | c.764G>C p.G255A | Missense Mutation (SNP) | VAF 18/347 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PHF24 | c.1105A>G p.R369G | Missense Mutation (SNP) | VAF 31/324 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- PHLDB2 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2
- PHOX2B | c.418G>T p.A140S | Missense Mutation (SNP) | VAF 21/492 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- PHTF1 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 57/743 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- PKHD1L1 | c.7635T>A p.F2545L | Missense Mutation (SNP) | VAF 40/416 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2
- PLA2G7 | c.537C>A p.H179Q | Missense Mutation (SNP) | VAF 28/476 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLA2R1 | c.1560G>C p.E520D | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); called by muse, mutect2
- PLB1 | c.618+2T>A p.X206_splice | Splice Site (SNP) | VAF 30/264 reads (11%) | called by muse, mutect2, varscan2
- PLB1 | c.1206G>T p.T402= | Splice Region (SNP) | VAF 46/630 reads (7%) | called by muse, mutect2
- PLIN4 | c.1775T>A p.V592E (on ENST00000301286; = p.V607E on NM_001367868.2) | Missense Mutation (SNP) | VAF 57/534 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PODN | c.1963G>T p.E655* (on ENST00000395871; = p.E607* on NM_153703.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- POGLUT2 | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.007); called by muse, mutect2
- POLG | c.3158C>T p.T1053I | Missense Mutation (SNP) | VAF 82/1028 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POLR1A | c.5122G>T p.G1708C | Missense Mutation (SNP) | VAF 46/603 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- POLR3A | c.3716A>T p.H1239L | Missense Mutation (SNP) | VAF 43/628 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- POTEE | c.2511G>C p.Q837H | Missense Mutation (SNP) | VAF 88/1284 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PPIAL4A | c.17T>A p.V6D | Missense Mutation (SNP) | VAF 36/562 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); called by muse, mutect2
- PRAMEF14 | c.293G>T p.W98L | Missense Mutation (SNP) | VAF 20/341 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2
- PRDM9 | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 54/424 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.099); called by muse, varscan2
- PRDM9 | c.1591C>A p.Q531K | Missense Mutation (SNP) | VAF 65/837 reads (8%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.54); called by muse, mutect2
- PRMT8 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 38/592 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2
- PRUNE2 | c.4444C>A p.P1482T | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PSKH2 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.066); called by muse, mutect2
- PTH2R | c.1480G>T p.G494C | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- R3HDM1 | c.510G>T p.M170I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- RAI1 | c.1903G>T p.D635Y | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- RASA3 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 30/409 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- RASSF8 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2
- RBM20 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 25/339 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- RBM20 | c.2261G>T p.S754I | Missense Mutation (SNP) | VAF 56/698 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, mutect2
- RBMXL3 | c.1697G>C p.G566A | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- RBMXL3 | c.2641C>A p.H881N | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.727); called by muse, mutect2
- RBP3 | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 51/802 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RCC2 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2
- REG3A | c.477A>T p.K159N | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2
- RGL1 | c.1999A>T p.I667F (on ENST00000360851 / NM_001297672.2; = p.I702F on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RGSL1 | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 28/590 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.109); called by muse, mutect2
- RIMS2 | c.3212G>T p.R1071I (on ENST00000666250 / NM_001348490.2; = p.R879I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- RP1L1 | c.6065G>T p.G2022V | Missense Mutation (SNP) | VAF 24/664 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.228); called by muse, mutect2
- RP1L1 | c.1757G>T p.S586I | Missense Mutation (SNP) | VAF 55/698 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2
- RPL30 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- RRP12 | c.2767G>T p.A923S | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.433); called by muse, mutect2
- RSL24D1 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.154); called by muse, mutect2
- RUBCN | c.2182A>G p.T728A | Missense Mutation (SNP) | VAF 43/786 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.093); called by muse, mutect2
- RUFY4 | c.259T>A p.F87I | Missense Mutation (SNP) | VAF 13/290 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by muse, mutect2
- RYR2 | c.14329G>T p.V4777F | Missense Mutation (SNP) | VAF 38/464 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RYR3 | c.5450G>T p.C1817F | Missense Mutation (SNP) | VAF 43/471 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2
- SAMD9 | c.4519G>C p.D1507H | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2
- SCARF1 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- SCN2A | c.1034G>A p.G345D | Missense Mutation (SNP) | VAF 44/449 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2
- SCN4A | c.3048G>T p.K1016N | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.073); called by muse, mutect2
- SCN4A | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 21/475 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SERPINA11 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 38/500 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SERPINC1 | c.581G>A p.S194N | Missense Mutation (SNP) | VAF 44/550 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- SETD2 | c.1990A>T p.R664* | Nonsense Mutation (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- SETD5 | c.3298G>T p.G1100W | Missense Mutation (SNP) | VAF 40/626 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); called by muse, mutect2
- SFMBT2 | c.112A>T p.S38C | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SGIP1 | c.1556C>T p.T519I | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- SH3GLB1 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 15/335 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.216); called by muse, mutect2
- SHC4 | c.1119del p.E373Dfs*13 | Frame Shift Del (DEL) | VAF 14/166 reads (8%) | called by mutect2, pindel
- SHOC2 | c.1149G>T p.K383N | Missense Mutation (SNP) | VAF 25/418 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2
- SHOC2 | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 23/395 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.255); called by muse, mutect2
- SHOX2 | c.131C>A p.T44N | Missense Mutation (SNP) | VAF 71/317 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SHROOM4 | c.1102G>T p.G368* | Nonsense Mutation (SNP) | VAF 79/1069 reads (7%) | called by muse, mutect2
- SIGLEC7 | c.784T>A p.S262T | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); called by muse, mutect2
- SLAMF6 | c.152A>T p.N51I | Missense Mutation (SNP) | VAF 36/375 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.062); called by muse, mutect2
- SLAMF9 | c.502A>G p.S168G | Missense Mutation (SNP) | VAF 46/766 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2
- SLC16A9 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.698); called by muse, mutect2
- SLC17A3 | c.336G>T p.W112C | Missense Mutation (SNP) | VAF 46/652 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC1A3 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 30/460 reads (7%) | called by muse, mutect2
- SLC1A6 | c.1075C>A p.P359T | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- SLC25A46 | c.877A>T p.K293* | Nonsense Mutation (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- SLC35F5 | c.926G>C p.G309A | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.334); called by muse, mutect2
- SLC44A5 | c.1409T>A p.F470Y | Missense Mutation (SNP) | VAF 35/538 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- SLC44A5 | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SLC44A5 | c.250A>T p.T84S | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by muse, mutect2
- SLC6A5 | c.1372T>A p.W458R | Missense Mutation (SNP) | VAF 22/651 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- SLC9C1 | c.1994C>A p.A665E | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- SLCO1B3 | c.818C>G p.S273C | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); called by muse, mutect2
- SLIT1 | c.938A>T p.E313V | Missense Mutation (SNP) | VAF 21/380 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.307); called by muse, mutect2
- SLITRK2 | c.2530C>G p.Q844E | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SMARCA1 | c.541G>T p.G181W | Missense Mutation (SNP) | VAF 24/590 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMARCAD1 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 34/415 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); called by muse, mutect2
- SMC3 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 29/400 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- SMG1 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 30/732 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SMPD4 | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 24/524 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.067); called by muse, mutect2
- SMPX | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 28/496 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- SNCA | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 44/733 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.303); called by muse, mutect2
- SND1 | c.2719G>A p.G907S | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SNX13 | c.1861del p.S621Afs*3 | Frame Shift Del (DEL) | VAF 44/413 reads (11%) | called by mutect2, pindel, varscan2
- SNX27 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 15/219 reads (7%) | called by muse, mutect2
- SNX31 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2
- SORCS1 | c.594C>A p.N198K | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- SORL1 | c.1127A>T p.E376V | Missense Mutation (SNP) | VAF 23/383 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SOX3 | c.1220C>A p.P407H | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPAM1 | c.601G>T p.V201L | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- SPATA31A3 | c.3317C>G p.P1106R | Missense Mutation (SNP) | VAF 55/828 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2
- SPATA31D1 | c.2441G>T p.G814V | Missense Mutation (SNP) | VAF 38/588 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.837); called by muse, mutect2
- SPIDR | c.1453G>T p.V485L | Missense Mutation (SNP) | VAF 76/960 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- SS18 | c.1106A>T p.Q369L (on ENST00000415083 / NM_001007559.3; = p.Q338L on NM_005637.3) | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- ST3GAL3 | c.131A>T p.H44L | Missense Mutation (SNP) | VAF 69/662 reads (10%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- STIM2 | c.1391G>A p.W464* | Nonsense Mutation (SNP) | VAF 50/533 reads (9%) | called by muse, mutect2
- SV2A | c.1934G>T p.G645V | Missense Mutation (SNP) | VAF 27/582 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.656); called by muse, mutect2
- TAF15 | c.718G>T p.G240* (on ENST00000605844 / NM_139215.3; = p.G237* on NM_003487.4) | Nonsense Mutation (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- TAS2R38 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 36/364 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.217); called by muse, mutect2
- TCEAL6 | c.317T>A p.V106E | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- TDRD5 | c.315T>G p.H105Q | Missense Mutation (SNP) | VAF 34/281 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- TECRL | c.446C>A p.A149D | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2
- TENT5D | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2
- TESPA1 | c.536C>T p.S179F (on ENST00000316577 / NM_001098815.3; = p.S41F on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2
- TEX13C | c.2321T>A p.L774Q | Missense Mutation (SNP) | VAF 38/954 reads (4%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.976); called by muse, mutect2
- TEX45 | c.1400T>A p.L467Q | Missense Mutation (SNP) | VAF 38/399 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2
- TFAP2B | c.1109T>A p.L370Q | Missense Mutation (SNP) | VAF 29/704 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TGM5 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 46/618 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2
- TIAL1 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 25/399 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2
- TIMM21 | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 21/549 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- TLR5 | c.2117G>T p.W706L | Missense Mutation (SNP) | VAF 32/424 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TLR5 | c.1684G>T p.A562S | Missense Mutation (SNP) | VAF 59/592 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMCO5A | c.616C>A p.Q206K | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2
- TMEM132A | c.1762C>A p.L588M (on ENST00000453848 / NM_178031.3; = p.L589M on NM_017870.4) | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- TMEM178A | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMLHE | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNXB | c.9747G>T p.E3249D (on ENST00000647633; = p.E3002D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/615 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); called by muse, mutect2
- TRAC | c.169T>A p.F57I | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2
- TRBV30 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM66 | c.65A>T p.N22I | Missense Mutation (SNP) | VAF 26/373 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIML2 | c.1130A>C p.E377A | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); called by muse, mutect2
- TRPC5 | c.2134C>G p.H712D | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- TRPV4 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 15/208 reads (7%) | called by muse, mutect2
- TSHZ3 | c.1663C>A p.Q555K | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- TTC28 | c.396G>T p.Q132H | Missense Mutation (SNP) | VAF 18/439 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- TTN | c.1612A>G p.R538G | Missense Mutation (SNP) | VAF 34/320 reads (11%) | PolyPhen benign (0.05); called by muse, mutect2, varscan2
- TUBB8B | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.769); called by muse, mutect2
- TUBGCP2 | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2
- TULP4 | c.3662A>T p.Q1221L | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- TUT7 | c.3223G>T p.D1075Y | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TYR | c.771del p.T258Qfs*61 | Frame Shift Del (DEL) | VAF 18/189 reads (10%) | called by mutect2, pindel
- UBE3C | c.508A>T p.R170* | Nonsense Mutation (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- UGT2B28 | c.87G>C p.W29C | Missense Mutation (SNP) | VAF 30/317 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- URI1 | c.1552G>T p.E518* | Nonsense Mutation (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2, varscan2
- USH2A | c.8965C>A p.P2989T | Missense Mutation (SNP) | VAF 34/576 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USP20 | c.2466G>A p.M822I | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- USP47 | c.1909G>T p.A637S (on ENST00000399455 / NM_001372095.1; = p.A549S on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/386 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- USP9X | c.2329G>T p.V777F | Missense Mutation (SNP) | VAF 20/331 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VAV3 | c.1160C>A p.S387Y | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- WDR25 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR87 | c.8179G>T p.E2727* | Nonsense Mutation (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- WHRN | c.853G>T p.G285W | Missense Mutation (SNP) | VAF 56/668 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- XCR1 | c.401C>A p.P134H | Missense Mutation (SNP) | VAF 40/504 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- XIRP2 | c.4714A>T p.T1572S (on ENST00000628543; = p.T1747S on NM_152381.6) | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.505); called by muse, mutect2
- XIRP2 | c.7507A>T p.S2503C (on ENST00000628543; = p.S2678C on NM_152381.6) | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.315); called by muse, mutect2
- XIRP2 | c.7508G>A p.S2503N (on ENST00000628543; = p.S2678N on NM_152381.6) | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- YBX3 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.341); called by muse, mutect2
- ZC3H3 | c.2155C>T p.H719Y | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZC3HAV1 | c.2678A>G p.Y893C | Missense Mutation (SNP) | VAF 36/661 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZER1 | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.368); called by muse, mutect2
- ZFHX3 | c.2262G>C p.M754I | Missense Mutation (SNP) | VAF 45/608 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.092); called by muse, mutect2
- ZFHX3 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 38/428 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.302); called by muse, mutect2
- ZFHX4 | c.673C>T p.H225Y | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFPM2 | c.1949C>A p.T650N | Missense Mutation (SNP) | VAF 42/762 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2
- ZNF195 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT tolerated (0.77); PolyPhen benign (0.006); called by muse, mutect2
- ZNF275 | c.28T>A p.L10M | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); called by muse, mutect2
- ZNF366 | c.1914G>T p.Q638H | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- ZNF445 | c.2219G>T p.G740V | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- ZNF469 | c.9644G>T p.R3215L (on ENST00000437464; = p.R3243L on NM_001367624.2) | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ZNF513 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 28/424 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- ZNF648 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2
- ZNF667 | c.1196C>A p.S399* | Nonsense Mutation (SNP) | VAF 13/175 reads (7%) | called by muse, mutect2
- ZNF681 | c.1145C>A p.T382N | Missense Mutation (SNP) | VAF 26/317 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.446); called by muse, mutect2
- ZNF80 | c.562C>G p.P188A | Missense Mutation (SNP) | VAF 20/319 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); called by muse, mutect2
- ZNF804B | c.2275A>T p.K759* | Nonsense Mutation (SNP) | VAF 17/217 reads (8%) | called by muse, mutect2
- ABCA4 | c.4134G>A p.V1378= | Silent (SNP) | VAF 38/685 reads (6%) | catalogued as rs1377803430; called by muse, mutect2
- ABCB11 | c.1506G>A p.E502= | Silent (SNP) | VAF 24/510 reads (5%) | called by muse, mutect2
- ABHD12B | c.606C>A p.T202= (on ENST00000337334 / NM_001206673.2; = p.T125= on NM_181533.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/399 reads (7%) | called by muse, mutect2
- ADAMTS16 | c.3306C>T p.S1102= | Silent (SNP) | VAF 29/581 reads (5%) | called by muse, mutect2
- ADCY2 | c.1860C>A p.L620= | Silent (SNP) | VAF 24/193 reads (12%) | catalogued as COSV57867202, COSV57871214; called by muse, mutect2, varscan2
- ADCY6 | c.777T>A p.A259= | Silent (SNP) | VAF 19/317 reads (6%) | called by muse, mutect2
- ADCY8 | c.2394G>T p.L798= | Silent (SNP) | VAF 20/212 reads (9%) | catalogued as COSV53926979; called by muse, mutect2
- ADCY9 | c.3381C>T p.D1127= | Silent (SNP) | VAF 34/301 reads (11%) | catalogued as rs370606217; called by muse, mutect2, varscan2
- ADGRB2 | c.3813A>C p.L1271= | Silent (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- ADGRG5 | c.666C>T p.R222= | Silent (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2
- ADPRH | c.585G>T p.L195= | Silent (SNP) | VAF 52/572 reads (9%) | called by muse, mutect2
- AMER3 | c.1053C>A p.P351= | Silent (SNP) | VAF 21/202 reads (10%) | called by muse, mutect2, varscan2
- ANKEF1 | c.1125G>T p.L375= | Silent (SNP) | VAF 45/517 reads (9%) | called by muse, mutect2
- ANKRD33B | c.819C>A p.P273= | Silent (SNP) | VAF 49/310 reads (16%) | called by muse, mutect2, varscan2
- ANKRD35 | c.504C>T p.I168= | Silent (SNP) | VAF 18/301 reads (6%) | catalogued as COSV62909497; called by muse, mutect2
- ASGR1 | c.429G>T p.A143= | Silent (SNP) | VAF 23/332 reads (7%) | called by muse, mutect2
- ASTN1 | c.1332C>A p.A444= | Silent (SNP) | VAF 20/226 reads (9%) | called by muse, mutect2
- ATP11B | c.1962G>A p.L654= | Silent (SNP) | VAF 24/292 reads (8%) | called by muse, mutect2
- ATP6V1E1 | c.132G>A p.R44= | Silent (SNP) | VAF 18/446 reads (4%) | called by muse, mutect2
- BAHCC1 | c.5937G>A p.T1979= | Silent (SNP) | VAF 16/372 reads (4%) | catalogued as rs375196947; called by muse, mutect2
- BCORL1 | c.1617T>A p.P539= | Silent (SNP) | VAF 13/200 reads (7%) | called by muse, mutect2
- BNC2 | c.885C>A p.P295= | Silent (SNP) | VAF 13/191 reads (7%) | catalogued as COSV66150952; called by muse, mutect2
- CACNA1G | c.1437C>T p.S479= | Silent (SNP) | VAF 14/196 reads (7%) | catalogued as rs1473783517; called by muse, mutect2
- CADM3 | c.489C>A p.L163= (on ENST00000368125 / NM_001127173.3; = p.L197= on NM_021189.5) | Silent (SNP) | VAF 23/255 reads (9%) | catalogued as rs554827373; called by muse, mutect2
- CCDC166 | c.1230C>T p.S410= | Silent (SNP) | VAF 21/319 reads (7%) | called by muse, mutect2
- CCDC171 | c.2433A>C p.A811= | Silent (SNP) | VAF 23/494 reads (5%) | called by muse, mutect2
- CCDC57 | c.1491C>T p.P497= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- CDH23 | c.2802C>A p.P934= | Silent (SNP) | VAF 32/483 reads (7%) | catalogued as COSV99824422; called by muse, mutect2
- CHRM3 | c.753C>T p.Y251= | Silent (SNP) | VAF 24/633 reads (4%) | called by muse, mutect2
- CHST6 | c.552C>T p.L184= | Silent (SNP) | VAF 42/676 reads (6%) | catalogued as rs1027441120; called by muse, mutect2
- CNTNAP2 | c.2478C>T p.Y826= | Silent (SNP) | VAF 22/550 reads (4%) | called by muse, mutect2
- CNTNAP5 | c.138C>A p.S46= | Silent (SNP) | VAF 28/390 reads (7%) | called by muse, mutect2
- COL24A1 | c.783A>G p.P261= | Silent (SNP) | VAF 11/166 reads (7%) | called by muse, mutect2
- COL4A1 | c.4917C>T p.S1639= | Silent (SNP) | VAF 66/878 reads (8%) | catalogued as rs1355587586, COSV101011614; called by muse, mutect2
- COL6A3 | c.2193C>T p.F731= | Silent (SNP) | VAF 22/458 reads (5%) | called by muse, mutect2
- CPT1C | c.1959C>T p.H653= | Silent (SNP) | VAF 12/348 reads (3%) | called by muse, mutect2
- CRISPLD1 | c.708A>G p.R236= | Silent (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- CSMD3 | c.3654A>C p.S1218= (on ENST00000297405 / NM_001363185.1; = p.S1114= on NM_052900.3) | Silent (SNP) | VAF 52/472 reads (11%) | called by muse, mutect2, varscan2
- CT47B1 | c.267C>G p.P89= | Silent (SNP) | VAF 111/913 reads (12%) | catalogued as rs761027895; called by muse, mutect2, varscan2
- CTSA | c.612G>T p.V204= | Silent (SNP) | VAF 52/673 reads (8%) | catalogued as rs768610868; called by muse, mutect2
- DCDC2B | c.492T>A p.T164= | Silent (SNP) | VAF 28/310 reads (9%) | called by muse, mutect2
- DHX36 | c.78A>G p.P26= | Silent (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- DNAH14 | c.306C>A p.R102= | Silent (SNP) | VAF 51/528 reads (10%) | called by muse, mutect2
- DPEP3 | c.114C>A p.T38= | Silent (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- DSP | c.1620C>G p.L540= | Silent (SNP) | VAF 52/634 reads (8%) | catalogued as COSV65793586; called by muse, mutect2
- EMD | c.315T>C p.Y105= | Silent (SNP) | VAF 28/791 reads (4%) | catalogued as rs1342409944, CM980600; ClinVar: likely benign; called by muse, mutect2
- ERBB4 | c.216G>T p.R72= | Silent (SNP) | VAF 16/392 reads (4%) | called by muse, mutect2
- ERN2 | c.1752C>T p.P584= | Silent (SNP) | VAF 29/284 reads (10%) | called by muse, mutect2, varscan2
- ESRRB | c.810G>T p.G270= | Silent (SNP) | VAF 30/296 reads (10%) | called by muse, mutect2, varscan2
- EXOG | c.801G>T p.V267= | Silent (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- EYA2 | c.867A>T p.T289= | Silent (SNP) | VAF 29/212 reads (14%) | called by muse, varscan2
- FAM166C | c.456C>A p.T152= | Silent (SNP) | VAF 23/161 reads (14%) | catalogued as rs200776859; called by muse, mutect2, varscan2
- FAM171A1 | c.612A>G p.T204= | Silent (SNP) | VAF 14/205 reads (7%) | called by muse, mutect2
- FAM228A | c.456G>T p.T152= | Silent (SNP) | VAF 34/309 reads (11%) | catalogued as rs1438413241; called by muse, mutect2, varscan2
- FLNC | c.2982C>A p.G994= | Silent (SNP) | VAF 48/563 reads (9%) | catalogued as COSV57964202; called by muse, mutect2
- FMO3 | c.300C>A p.L100= | Silent (SNP) | VAF 28/408 reads (7%) | called by muse, mutect2
- FNDC1 | c.2928G>A p.A976= | Silent (SNP) | VAF 23/314 reads (7%) | catalogued as COSV51945027, COSV99795736; called by muse, mutect2
- FOLH1 | c.321T>C p.S107= | Silent (SNP) | VAF 40/512 reads (8%) | catalogued as rs756966079; called by muse, mutect2
- FOXL1 | c.687G>T p.A229= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- FOXP2 | c.1432C>A p.R478= | Silent (SNP) | VAF 16/361 reads (4%) | called by muse, mutect2
- GALNT13 | c.15C>T p.V5= | Silent (SNP) | VAF 19/148 reads (13%) | called by muse, mutect2, varscan2
- GCLC | c.15G>A p.P5= (on ENST00000643939; = p.P9= on NM_001498.4) | Silent (SNP) | VAF 25/306 reads (8%) | catalogued as rs780375640; called by muse, mutect2
- GDF6 | c.723C>T p.D241= | Silent (SNP) | VAF 17/277 reads (6%) | catalogued as rs1426341298; called by muse, mutect2
- GIN1 | c.1347A>G p.G449= | Silent (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2
- GPR26 | c.402G>T p.A134= | Silent (SNP) | VAF 27/246 reads (11%) | catalogued as rs1210799362; called by muse, mutect2
- GSTM5 | c.306C>T p.N102= | Silent (SNP) | VAF 33/455 reads (7%) | catalogued as rs373590757; called by muse, mutect2
- HAS1 | c.753G>T p.V251= | Silent (SNP) | VAF 24/388 reads (6%) | catalogued as rs1433977319; called by muse, mutect2
- HDAC5 | c.1281G>T p.L427= | Silent (SNP) | VAF 7/70 reads (10%) | called by mutect2, varscan2
- HFM1 | c.2106A>T p.A702= | Silent (SNP) | VAF 19/296 reads (6%) | called by muse, mutect2
- HTR2A | c.252G>T p.V84= | Silent (SNP) | VAF 22/344 reads (6%) | called by muse, mutect2
- HTR5A | c.1011C>A p.I337= | Silent (SNP) | VAF 16/354 reads (5%) | called by muse, mutect2
- IGHV1-18 | c.12C>A p.T4= | Silent (SNP) | VAF 21/485 reads (4%) | called by muse, mutect2
- IGKV1D-42 | c.72C>A p.I24= | Silent (SNP) | VAF 12/187 reads (6%) | called by muse, mutect2
- IL17A | c.126C>A p.P42= | Silent (SNP) | VAF 38/575 reads (7%) | catalogued as COSV100391710; called by muse, mutect2
- IRF4 | c.1041C>A p.P347= | Silent (SNP) | VAF 36/460 reads (8%) | called by muse, mutect2
- ITGA2B | c.2148G>T p.V716= | Silent (SNP) | VAF 50/738 reads (7%) | called by muse, mutect2
- ITGA8 | c.1344C>A p.S448= | Silent (SNP) | VAF 40/316 reads (13%) | called by muse, mutect2, varscan2
- JUP | c.189G>A p.Q63= | Silent (SNP) | VAF 26/482 reads (5%) | catalogued as COSV60277490; called by muse, mutect2
- KCNG1 | c.892C>A p.R298= | Silent (SNP) | VAF 20/179 reads (11%) | called by muse, mutect2, varscan2
- KIF13A | c.1878G>T p.R626= | Silent (SNP) | VAF 44/698 reads (6%) | catalogued as COSV52445441; called by muse, mutect2
- KIF13A | c.570C>G p.V190= | Silent (SNP) | VAF 9/158 reads (6%) | catalogued as COSV99435329; called by muse, mutect2
- KMT2D | c.13260G>T p.R4420= | Silent (SNP) | VAF 32/442 reads (7%) | called by muse, mutect2
- LAMA1 | c.2577G>A p.E859= | Silent (SNP) | VAF 56/678 reads (8%) | catalogued as COSV67546033; called by muse, mutect2
- LAMB1 | c.3003G>T p.L1001= | Silent (SNP) | VAF 24/574 reads (4%) | called by muse, mutect2
- LRFN3 | c.651C>T p.T217= | Silent (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- MAN1A1 | c.270C>T p.P90= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs1040239021; called by muse, mutect2, varscan2
- MDGA1 | c.2511C>T p.F837= | Silent (SNP) | VAF 18/304 reads (6%) | called by muse, mutect2
- MED14 | c.2271T>C p.V757= | Silent (SNP) | VAF 20/201 reads (10%) | called by muse, mutect2, varscan2
- MICAL1 | c.420T>G p.A140= | Silent (SNP) | VAF 18/413 reads (4%) | called by muse, mutect2
- MTSS2 | c.1341G>T p.L447= | Silent (SNP) | VAF 17/210 reads (8%) | called by muse, mutect2
- MUC16 | c.6276C>A p.L2092= | Silent (SNP) | VAF 14/249 reads (6%) | called by muse, mutect2
- MUC4 | c.13191G>T p.P4397= (on ENST00000463781 / NM_018406.7; = p.P161= on NM_004532.6) | Silent (SNP) | VAF 14/380 reads (4%) | called by muse, mutect2
- NRG3 | c.2010G>A p.R670= (on ENST00000404547 / NM_001370084.1; = p.R646= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 32/398 reads (8%) | called by muse, mutect2
- OR10Z1 | c.774G>A p.V258= | Silent (SNP) | VAF 46/347 reads (13%) | catalogued as COSV63524752; called by muse, mutect2, varscan2
- OR1C1 | c.276C>A p.I92= | Silent (SNP) | VAF 12/192 reads (6%) | catalogued as rs1222230537; called by muse, mutect2
- OR5D13 | c.717T>A p.T239= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV62334022; called by muse, mutect2
- OR5D18 | c.633A>T p.T211= | Silent (SNP) | VAF 53/624 reads (8%) | called by muse, mutect2
- OR5M8 | c.693G>A p.E231= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as rs1362355859; called by muse, mutect2
185 further variants in this file (0 protein-altering or splice-affecting, 68 silent, 117 other) are not listed here.
